Surgical pathology report (de-identified scan), TCGA case TCGA-16-1045, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Toronto Western Hospital, specimen TCGA-16-1045-01B (Primary Tumor).

[page 1 of 2]
Patient Name: [REDACTED] Copath #: [REDACTED]
MRN: [REDACTED] Service: Surgical Service Collected: [REDACTED]
DOB: [REDACTED] Visit #: [REDACTED] Resulted: [REDACTED]
Gender: F Location: [REDACTED]
ICN: [REDACTED] Facility: [REDACTED]
Ordering MD: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED
1. BRN: Rt. side brain tumour parietal for QS
2. Brain- right multi frontal brain tumour

DIAGNOSIS
Glioblastoma multiforme with zones of oligodendroglial differentiation.

COMMENT
Because of the zones of oligodendroglial differentiation, molecular genetic testing for 1p19q deletions will be performed.

GROSS DESCRIPTION
1. The specimen container is labeled with the patient's name and as "right side brain tumor parietal" contains a single piece of a red-tan tissue measuring 0.5 x 0.3 x 0.3 received fresh. This is examined at intraoperative consultation by frozen section performed on part of the specimen.
1A frozen section resubmitted.
1B the rest submitted in toto
2. The specimen container labeled with the patient's name and as "right multi frontal brain tumor ", contains multiple fragments of red-tan tissue, received in 10% buffered formalin. In aggregate this measures 5.8 x 4.9 x 3.0 cm and weighs 23.0 gm.
2A-2F - representative tissue submitted

[page 2 of 2]
[REDACTED]

Patient Name: [REDACTED] Copath #: [REDACTED]
MRN: [REDACTED] Service: Surgical Service Collected [REDACTED]
DOB: [REDACTED] Visit #: [REDACTED] Resulted: [REDACTED]
Gender: F Location: [REDACTED]
HCN: [REDACTED] Facility: [REDACTED]
Ordering MD: [REDACTED]

QUICK SECTION

Cellular pleomorphic infiltrate with process, eosinophilic cytoplasm, in keeping with a high-grade glioma.
Cannot exclude an anaplastic oligodendroglioma.

[REDACTED]

MICROSCOPIC DESCRIPTION

The specimen consists of a tumor with highly anaplastic cells, zones of necrosis, pseudopalisading, neovascularization and multinucleated tumor cells. While in many areas, the tumor cells have peripheral, eosinophilic cytoplasm, in other areas the cells show cytoplasmic clearing and there is a prominent cross-hatched capillary network. GFAP immunohistochemistry shows much greater cytoplasmic positivity in the cells with eosinophilic cytoplasm than in those with clear cytoplasm. A proliferation index obtained with MIB1/Ki67 immunohistochemistry is greater than 25%.

Source: NCI Genomic Data Commons file 80c56ece-b773-4cf8-9f68-24c8121de9e2 (TCGA-16-1045.F47EF3FB-4402-4D51-A2CF-01FBFAA813A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).